Somatic mutation profile of tumor specimen TARGET-10-PARNSW-09A (aliquot TARGET-10-PARNSW-09A-01D) from TARGET case TARGET-10-PARNSW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (5,015 days).
Specimen TARGET-10-PARNSW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2dde657-1bdd-48df-bec1-de99d84371b2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARNSW-10A (Blood Derived Normal), aliquot TARGET-10-PARNSW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47e6649e-77e1-4cca-9ecc-b9306c6dcb2f

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Nonsense Mutation 1, Splice Site 1, Intron 1, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as rs202183313; called by muse, mutect2, varscan2
- DNER | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as rs143332732; called by muse, mutect2, varscan2
- PRR23C | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs1201851082; called by muse, mutect2, varscan2
- RIMS1 | c.3088C>T p.R1030* | Nonsense Mutation (SNP) | VAF 27/135 reads (20%) | catalogued as COSV53446586, COSV53477554; called by muse, mutect2, varscan2
- ADAM17 | c.2018T>C p.V673A | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- DNAH17 | c.4165A>G p.N1389D | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- SNX14 | c.1389+1G>A p.X463_splice (on ENST00000314673 / NM_001350535.1; = p.X419_splice on NM_020468.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2, varscan2
- TRGJ2 | c.10_11insG p.K5Efs*? | Frame Shift Ins (INS) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- UBE2A | c.261_266del p.I87_L89delinsM | In Frame Del (DEL) | VAF 26/42 reads (62%) | called by mutect2, pindel, varscan2
- KLB | c.2178C>T p.Y726= | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as rs560924478; called by muse, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 6/36 reads (17%) | catalogued as rs201441562; called by pindel, varscan2
- LOXL2 | chr8:23404174 C>T | 5'Flank (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
